Gene-level copy-number profile of tumor specimen TCGA-AR-A0TU-01A from TCGA case TCGA-AR-A0TU, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 35.7 years (13,039 days).
Specimen TCGA-AR-A0TU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.ebd66787-d03c-41f8-9054-ec39f4d0304f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A0TU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate.
https://portal.gdc.cancer.gov/files/22a89970-ac4a-4bce-858e-2bb719c2990e

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 33,481; copy number 2: 21,761; copy number 3: 3,998; copy number 4: 475.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:220,105,656–220,855,873, 5 genes: AC019211.1, AC093083.1, AC067956.1, AC093843.1, AC093843.2.
- chr2:227,666,804–228,841,689, 19 genes: SCYGR5, SLC19A3, SCYGR6, SCYGR7, SCYGR8, RNA5SP121, SNRPGP8, AC073065.1, CCL20, TDGF1P2, DAW1, AC073065.2, SPHKAP, RNU6-624P, SNF8P1, AC009410.1, LINC01807, AC012070.1, RPL7L1P10.
- chr5:9,363,275–9,422,481, 1 gene (within-gene range 0–1): AC091906.1.
- chr6:50,818,723–50,913,256, 4 genes: TFAP2B, RPS17P5, AL049693.1, FTH1P5.
- chr7:33,094,797–35,699,413, 33 genes: RP9, BBS9, AC074338.1, RNA5SP229, AC007312.1, AC006195.1, AC008080.1, AC008080.2, AC008080.4, AC008080.3, BMPER, AC007350.1, AC009262.1, RNU6-438P, NPSR1-AS1, NPSR1, RPL7P31, NCAPD2P1, RN7SL132P, AC004788.1, DPY19L1, MIR548N, AC005400.1, DPY19L2P1, S100A11P2, TBX20, AC009531.1, AC007652.3, AC007652.2, AC007652.1, AC018647.3, HERPUD2, AC018647.2.
- chr13:48,134,358–49,209,779, 22 genes (within-gene range 0–1): POLR2KP2, ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1.
- chr20:12,243,308–13,300,651, 12 genes: AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,026 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:77,779,624–77,879,539, 1 gene, copy number 3 (within-gene range 2–3): MIGA1.
- chr1:77,810,861–78,369,464, 16 genes, copy number 3 (within-gene range 2–3): AC138392.1, NSRP1P1, HSPE1P25, NEXN-AS1, NEXN, FUBP1, DNAJB4, GIPC2, AC103591.3, AC103591.4, AC103591.2, RNU6-1102P, AC103591.1, RNA5SP22, RNFT1P2, MGC27382.
- chr1:78,317,157–78,317,263, 1 gene, copy number 3: AC096531.1.
- chr1:85,249,953–89,290,337, 69 genes, copy number 3 (broad region; genes not listed).
- chr1:164,980,035–165,911,618, 21 genes, copy number 3 (within-gene range 2–3): RNU6-755P, LMX1A, LMX1A-AS2, LMX1A-AS1, RXRG, LRRC52-AS1, PRELID1P7, LRRC52, AL356441.2, AL356441.1, MGST3, ALDH9A1, Y_RNA, AL451074.3, AL451074.2, AL451074.1, AL451074.5, TMCO1, TMCO1-AS1, AL451074.4, UCK2.
- chr1:168,695,468–184,335,949, 308 genes, copy number 3 (broad region; genes not listed).
- chr1:235,127,803–248,919,946, 325 genes, copy number 3 (broad region; genes not listed).
- chr2:95,807,052–97,739,862, 69 genes, copy number 3 (broad region; genes not listed).
- chr3:2,985,231–3,627,296, 8 genes, copy number 4 (within-gene range 2–4): DNAJC19P4, CNTN4-AS1, IL5RA, AC024060.1, TRNT1, CRBN, AC024060.2, AC034195.1.
- chr4:186,587,794–190,092,279, 67 genes, copy number 3 (broad region; genes not listed).
- chr6:53,090,961–54,390,142, 34 genes, copy number 3: RN7SL244P, AL512347.1, GCM1, RNU6-464P, SOD1P1, AL512378.1, RNU1-136P, HMGB1P20, ELOVL5, MIR5685, RPS16P5, AL034374.1, RPL31P28, RPL31P33, RPA3P2, AL591034.1, RN7SKP256, NANOGP3, GCLC, AL033397.2, AL033397.1, LINC01564, KLHL31, AL590652.1, LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1.
- chr6:118,452,469–142,088,799, 328 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr6:151,404,762–152,129,619, 9 genes, copy number 4: RMND1, HSPA8P15, ARMT1, CCDC170, RNU6-813P, ESR1, AL356311.1, AL078582.2, AL078582.1.
- chr7:118,880,103–119,907,397, 4 genes, copy number 3 (within-gene range 2–3): GTF3AP6, AC092098.1, AC079791.1, LINC02476.
- chr7:158,957,497–159,233,377, 5 genes, copy number 3: AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:737,628–1,708,476, 1 gene, copy number 3 (within-gene range 2–3): DLGAP2.
- chr8:1,246,789–1,801,711, 11 genes, copy number 3: AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1.
- chr8:1,801,125–1,817,307, 3 genes, copy number 3: MIR3674, AC100810.7, MIR596.
- chr8:104,590,733–105,804,539, 1 gene, copy number 3 (within-gene range 2–3): ZFPM2.
- chr8:104,981,164–130,655,712, 299 genes, copy number 3 (broad region; genes not listed).
- chr8:132,507,962–133,134,903, 9 genes, copy number 4 (within-gene range 2–4): HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1.
- chr10:44,712–16,207,927, 284 genes, copy number 3 (broad region; genes not listed).
- chr10:50,305,586–50,625,163, 1 gene, copy number 3 (within-gene range 2–3): SGMS1.
- chr10:50,472,814–64,693,446, 125 genes, copy number 3 (broad region; genes not listed).
- chr12:66,767–7,240,986, 226 genes, copy number 3–4 (broad region; genes not listed).
- chr13:19,126,399–19,865,048, 28 genes, copy number 4 (within-gene range 2–4): CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1, PSPC1P1, ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2, TPTE2, CYCSP32, MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P, ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2.
- chr13:22,040,972–22,916,369, 11 genes, copy number 3 (within-gene range 1–3): LINC00540, NME1P1, MTND3P1, AL512484.1, FTH1P7, DDX39AP1, SNORD36, RPL7AP73, IPMKP1, RFESDP1, LINC00621.
- chr13:38,050,817–39,791,665, 19 genes, copy number 3 (within-gene range 1–3): LINC00571, UFM1, AL356863.1, LINC00437, LINC00366, PRDX3P3, FREM2, RNU6-56P, FREM2-AS1, PLA2G12AP2, ANKRD26P2, STOML3, PROSER1, NHLRC3, AL354809.1, NXT1P1, LHFPL6, COG6, MIR4305.
- chr14:22,105,343–24,657,774, 233 genes, copy number 3 (broad region; genes not listed).
- chr14:24,818,385–24,865,978, 2 genes, copy number 3: AL161663.2, AL161663.1.
- chr16:82,044,336–82,575,518, 7 genes, copy number 4 (within-gene range 2–4): AC092142.1, MTCYBP28, MPHOSPH6, AC138304.1, RN7SKP190, AC009117.1, AC009117.2.
- chr16:82,688,931–82,844,757, 5 genes, copy number 4: MIR8058, AC099506.2, AC099506.1, AC099506.3, RN7SL134P.
- chr18:43,499,173–49,461,347, 95 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr18:62,300,036–80,247,514, 257 genes, copy number 3 (broad region; genes not listed).
- chr20:22,885,670–23,990,454, 48 genes, copy number 3: CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93, LINC00656, AL118508.2, RNA5SP478, AL118508.1, AL390037.1, NXT1-AS1, NXT1, LINC01431, GZF1, NAPB, RNA5SP479, CSTL1, CST11, AL096677.1, Y_RNA, CST12P, AL109954.1, AL109954.2, CST8, CST13P, CST9LP1, CST9L, CST9LP2, CST9, CST3, AL121894.2, AL121894.1, AL121894.3, CST4, CST2P1, AL591074.2, CST1, CSTP2, AL591074.1, CST2, CST5, CSTP1, AL133466.1, GGTLC1, POM121L3P.
- chr21:34,787,801–36,004,667, 1 gene, copy number 3 (within-gene range 2–3): RUNX1.
- chr21:35,472,095–39,321,559, 95 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 32,573. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
